Somatic mutation profile of cancer-model specimen HCM-BROD-0103-C71-85B (3D Neurosphere, passage 10; aliquot HCM-BROD-0103-C71-85B-01D-A78T-36), derived from the primary tumor of HCMI case HCM-BROD-0103-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,295 days).
Specimen HCM-BROD-0103-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26d0e2d3-a1fb-495d-b465-aca96f4ea77f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0103-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0103-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18c33765-e843-4b97-ab17-6a57f98bdf4d

The open-access MAF lists 722 somatic variants for this specimen: 478 protein-altering or splice-affecting, 156 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 156, Frame Shift Del 52, Intron 51, Nonsense Mutation 22, Frame Shift Ins 21, 3'UTR 11, In Frame Del 10, RNA 10, Splice Region 8, Splice Site 8, 5'UTR 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5Z1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 39/82 reads (48%) | catalogued as rs748724870; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFAP44 | c.3175C>T p.R1059* | Nonsense Mutation (SNP) | VAF 140/309 reads (45%) | catalogued as rs1262272674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLDN16 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 222/466 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs765256758, CM015915, COSV53228629, COSV99290296; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COX14 | c.81dup p.Y28Vfs*39 | Frame Shift Ins (INS) | VAF 120/447 reads (27%) | catalogued as rs34028295; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ESCO2 | c.1131+1G>A p.X377_splice | Splice Site (SNP) | VAF 185/379 reads (49%) | catalogued as rs80359861, CS054187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 272/667 reads (41%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 163/390 reads (42%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 72/230 reads (31%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 43/112 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 71/187 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
- SGCA | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 234/521 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); catalogued as rs371675217, CM163140, CM951149, COSV56249347; ClinVar: pathogenic; called by muse, varscan2
- TMLHE | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782785654, COSV57686403; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 263/502 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 245/552 reads (44%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 68/164 reads (41%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCC3 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163700000, COSV53319611; called by muse, mutect2, varscan2
- ABCF1 | c.1369C>T p.R457C (on ENST00000326195 / NM_001025091.2; = p.R419C on NM_001090.3) | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772178279, COSV100400987; called by muse, mutect2, varscan2
- AC006059.2 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as rs1193298603, COSV58414753; called by muse, mutect2, varscan2
- ADAM8 | c.875+1G>A p.X292_splice | Splice Site (SNP) | VAF 34/62 reads (55%) | catalogued as COSV101291634; called by muse, mutect2, varscan2
- ADAMTS13 | c.3616C>T p.R1206* | Nonsense Mutation (SNP) | VAF 328/1125 reads (29%) | catalogued as rs782818582, CM063839; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369487048, COSV57871248; called by muse, mutect2, varscan2
- ADGRA3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99293741; called by muse, mutect2, varscan2
- AGBL4 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as rs1345349497; called by muse, mutect2, varscan2
- AGPS | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 36/619 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as rs1484968124; called by muse, mutect2
- AIFM3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 177/376 reads (47%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.767); catalogued as rs150801089; called by muse, mutect2, varscan2
- AKAP12 | c.2846C>T p.T949M | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs766910226, COSV53572564; called by muse, mutect2
- ALAS1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 225/439 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs773796345, COSV59630314; called by muse, mutect2, varscan2
- ALPP | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 28/652 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101235088; called by muse, mutect2
- ANKRD66 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs1046780145; called by muse, mutect2, varscan2
- ANKS1B | c.3131C>T p.P1044L (on ENST00000547776 / NM_152788.4; = p.P210L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/431 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs764918916, COSV100227903; called by muse, mutect2, varscan2
- AP1M2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 170/329 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs370653364; called by muse, mutect2, varscan2
- ARAP1 | c.1750G>A p.V584I (on ENST00000393609 / NM_001040118.2; = p.V339I on NM_015242.4) | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201267929; called by muse, mutect2, varscan2
- ARHGEF17 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1046539421; called by muse, mutect2, varscan2
- ARSI | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60816809; called by muse, mutect2, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 62/128 reads (48%) | catalogued as rs773893016; called by mutect2, varscan2
- ASB2 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 103/103 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs765782110, COSV60112128; called by muse, mutect2, varscan2
- ATOX1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1026147447; called by muse, mutect2, varscan2
- ATP13A1 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 192/456 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1306584228; called by mutect2, varscan2
- ATP2B3 | c.3214G>C p.G1072R | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.181); catalogued as rs1302738555; called by muse, mutect2, varscan2
- ATP5IF1 | c.247_249del p.K83del | In Frame Del (DEL) | VAF 66/160 reads (41%) | catalogued as rs746429737; called by pindel, varscan2
- BAHCC1 | c.853_855del p.L285del | In Frame Del (DEL) | VAF 36/87 reads (41%) | catalogued as rs781915534; called by pindel, varscan2
- BCAR3 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 161/322 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs767751704; called by muse, mutect2, varscan2
- BCCIP | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs375172899; called by muse, mutect2, varscan2
- BRD2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 235/455 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs771459465, COSV66374414; called by muse, mutect2, varscan2
- C2orf16 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 186/376 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.062); catalogued as rs974882283; called by muse, mutect2, varscan2
- CACNA1H | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 158/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756266849, COSV61993629; called by muse, mutect2, varscan2
- CACNA1S | c.3760C>T p.R1254* | Nonsense Mutation (SNP) | VAF 302/662 reads (46%) | catalogued as rs200034567, COSV104423916; called by muse, mutect2, varscan2
- CARD9 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 359/562 reads (64%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as rs369865691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAST | c.728C>T p.S243L (on ENST00000341926; = p.S326L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777835139; called by muse, mutect2, varscan2
- CDC42BPB | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1184748794, COSV100775556; called by muse, mutect2, varscan2
- CDC42BPB | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766213299; called by muse, mutect2, varscan2
- CECR2 | c.3199G>A p.A1067T (on ENST00000342247 / NM_001290047.2; = p.A883T on NM_001290046.1) | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1193253270; called by muse, mutect2, varscan2
- CELSR1 | c.5032C>T p.R1678* | Nonsense Mutation (SNP) | VAF 156/300 reads (52%) | catalogued as rs1395192638, COSV53084327; called by muse, mutect2, varscan2
- CEP120 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs375645626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP250 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 108/268 reads (40%) | catalogued as rs1345217165, COSV61170521; called by muse, mutect2, varscan2
- CHD6 | c.3239C>T p.T1080M | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs778940797; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 73/144 reads (51%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRNA10 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 151/311 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV51703122; called by muse, mutect2, varscan2
- CHRNB1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 381/810 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs202080837, COSV53438818; called by muse, mutect2, varscan2
- CNBD2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 113/227 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372174146; called by muse, mutect2, varscan2
- CNDP2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 72/83 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs543311440, COSV60839699; called by muse, mutect2, varscan2
- CNKSR1 | c.1871G>A p.R624Q (on ENST00000374253 / NM_001297647.2; = p.R617Q on NM_006314.3) | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370754955; called by muse, mutect2, varscan2
- CNN1 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755937649, COSV52948059; called by muse, mutect2, varscan2
- CNNM3 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 96/171 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs375599243; called by muse, mutect2, varscan2
- CNOT2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 152/473 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs755578360, COSV57507432; called by muse, mutect2, varscan2
- CNTN3 | c.2134G>A p.G712R | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777506457, COSV55166710; called by muse, mutect2, varscan2
- COL22A1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 176/385 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs753278763, COSV57328854; called by muse, varscan2
- COL22A1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 194/424 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs767596054, COSV100279026; called by muse, varscan2
- COL26A1 | c.648dup p.G217Rfs*3 (on ENST00000313669 / NM_001278563.3; = p.G215Rfs*3 on NM_133457.4) | Frame Shift Ins (INS) | VAF 122/280 reads (44%) | catalogued as rs762324149; called by mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 109/289 reads (38%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 44/92 reads (48%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYGA | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs759998672; called by muse, mutect2, varscan2
- CSMD2 | c.7949C>T p.T2650M | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs766108599; called by muse, mutect2, varscan2
- CSNK1D | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 386/793 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs773629124; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 66/167 reads (40%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTF1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 94/176 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753956418; called by muse, mutect2, varscan2
- CTPS2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs200862252, COSV100826912; called by muse, mutect2, varscan2
- CXorf66 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs937663859, COSV65169489; called by muse, mutect2, varscan2
- CYSRT1 | c.346G>A p.A116T (on ENST00000409414; = p.A76T on NM_199001.5) | Missense Mutation (SNP) | VAF 23/702 reads (3%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as rs983681320; called by muse, mutect2
- DAB2IP | c.2951G>A p.R984Q (on ENST00000408936; = p.R956Q on NM_032552.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs767407304; called by muse, varscan2
- DDC | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 319/609 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1285477390, CM155193, COSV100779145; called by muse, mutect2, varscan2
- DDX54 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs373380709; called by muse, mutect2, varscan2
- DEF8 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as rs770936185; called by muse, mutect2, varscan2
- DENND1C | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757345339, COSV57568183; called by muse, mutect2, varscan2
- DENND4A | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921739451; called by muse, mutect2, varscan2
- DIAPH3 | c.796G>A p.E266K (on ENST00000400324 / NM_001042517.2; = p.E3K on NM_030932.3) | Missense Mutation (SNP) | VAF 87/204 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as COSV57383239; called by muse, mutect2, varscan2
- DIDO1 | c.4261C>T p.R1421W | Missense Mutation (SNP) | VAF 180/646 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs374108825; called by muse, mutect2, varscan2
- DKKL1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 159/697 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs553391194; called by muse, mutect2, varscan2
- DMD | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 56/231 reads (24%) | catalogued as CM033766; called by muse, mutect2, varscan2
- DNAH1 | c.7186C>T p.R2396W | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs771741555; called by muse, mutect2, varscan2
- DNAI3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1389668154; called by muse, mutect2, varscan2
- DNAJB14 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs759384909; called by muse, mutect2, varscan2
- DNAJC6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762184162; called by muse, mutect2, varscan2
- DND1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as rs1173484763; called by muse, mutect2
- DNMT3A | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 172/324 reads (53%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1299885148; called by muse, mutect2, varscan2
- DNTTIP2 | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 87/189 reads (46%) | catalogued as rs757095161, COSV63283589, COSV63284176; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPP4 | c.2125+2T>C p.X709_splice | Splice Site (SNP) | VAF 100/181 reads (55%) | catalogued as rs1202315950; called by muse, mutect2, varscan2
- DUOX2 | c.2161A>G p.S721G | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1311602820; called by muse, mutect2
- DUOXA1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 188/400 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs374219066; called by muse, mutect2, varscan2
- DYSF | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 225/561 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as rs146261069, COSV50459563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECEL1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 174/333 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs762886790, COSV58813980; called by muse, mutect2, varscan2
- ELMO2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 102/209 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as COSV99281523; called by muse, mutect2, varscan2
- ENPP1 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 168/336 reads (50%) | catalogued as COSV62930392; called by muse, mutect2, varscan2
- EP400 | c.8330C>T p.T2777M | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1278138582; called by muse, varscan2
- ERBB4 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 154/319 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.674); catalogued as rs775988789, COSV53516370, COSV99626233; called by muse, mutect2, varscan2
- ERFE | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 197/458 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.02); catalogued as COSV60137721; called by muse, mutect2, varscan2
- EZHIP | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 219/461 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs781803102, COSV57955344; called by muse, mutect2, varscan2
- F13A1 | c.2068G>A p.V690M | Missense Mutation (SNP) | VAF 211/451 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs762504395, COSV53559531; called by muse, mutect2, varscan2
- FAM135B | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs554108334, COSV52704532; called by muse, mutect2, varscan2
- FAM151A | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 192/407 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs766394836; called by muse, mutect2, varscan2
- FAM214B | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1398814777, COSV59714987; called by muse, mutect2
- FAM222A | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 225/369 reads (61%) | SIFT tolerated (0.64); PolyPhen benign (0.068); catalogued as rs1373319522; called by muse, mutect2, varscan2
- FARP1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 97/201 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs747461832, COSV60348215; called by muse, mutect2, varscan2
- FARP2 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 286/563 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs151203664; called by muse, mutect2, varscan2
- FAT2 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs773729288, COSV55814904; called by muse, mutect2, varscan2
- FBXO36 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 154/286 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs747143681; called by muse, mutect2, varscan2
- FER1L4 | n.2878C>T | Splice Region (SNP) | VAF 83/178 reads (47%) | catalogued as rs894180329; called by muse, mutect2, varscan2
- FGFR4 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 118/212 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.063); catalogued as rs550870047; called by muse, mutect2, varscan2
- FHOD1 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 213/424 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775105803; called by muse, mutect2, varscan2
- FIBIN | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs367758269; called by muse, mutect2, varscan2
- FIZ1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 59/60 reads (98%) | SIFT tolerated (0.61); PolyPhen benign (0.04); catalogued as COSV99684385; called by muse, mutect2, varscan2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 50/108 reads (46%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- FUT1 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 266/587 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778160774, COSV59569709; called by muse, mutect2, varscan2
- GALNT10 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760742738, COSV99769956; called by muse, mutect2, varscan2
- GALNT16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761614171, COSV61886308; called by muse, mutect2, varscan2
- GALNT17 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 160/334 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974898586, COSV61155556; called by muse, varscan2
- GALNT6 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 171/491 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1242187044; called by muse, mutect2, varscan2
- GLIS1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs779399927, COSV56556296; called by muse, mutect2, varscan2
- GLYCTK | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 262/633 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs761292284; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 67/146 reads (46%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR157 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs373046894; called by muse, mutect2
- GPR45 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV51523391; called by muse, mutect2
- GRAMD4 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs761767100; called by muse, mutect2, varscan2
- GRB7 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs773643597, COSV100485412; called by muse, mutect2, varscan2
- GUCD1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs749512927; called by muse, mutect2
- HAND2 | c.247dup p.V83Gfs*260 | Frame Shift Ins (INS) | VAF 44/110 reads (40%) | catalogued as rs756064749; called by mutect2, varscan2
- HELZ2 | c.4909G>A p.D1637N (on ENST00000467148 / NM_001037335.2; = p.D1068N on NM_033405.3) | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1391635907; called by muse, mutect2, varscan2
- HFM1 | c.4163dup p.N1388Kfs*8 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | catalogued as rs759278255, COSV99646600; called by mutect2, varscan2
- HIPK2 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 123/281 reads (44%) | catalogued as COSV100702668; called by muse, mutect2, varscan2
- HK3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 145/302 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs781200940, COSV52837709; called by muse, mutect2, varscan2
- HKDC1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 135/311 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs200818764, COSV63577650; called by muse, mutect2, varscan2
- HPDL | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 166/379 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs765146959, COSV58343507; called by muse, mutect2, varscan2
- HTT | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs955972991, COSV61858562; called by muse, mutect2, varscan2
- IGF1R | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 290/614 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375391097; called by muse, mutect2, varscan2
- IGSF10 | c.2803del p.M935Cfs*11 | Frame Shift Del (DEL) | VAF 140/382 reads (37%) | catalogued as COSV56783028; called by mutect2, pindel, varscan2
- IL1RAPL1 | c.1901C>A p.P634H | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV56291252; called by muse, mutect2, varscan2
- INTS1 | c.3496G>A p.V1166M | Missense Mutation (SNP) | VAF 156/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs984511351; called by muse, mutect2, varscan2
- IQCF1 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs754921110; called by muse, mutect2, varscan2
- IQSEC1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs750405546; called by muse, mutect2, varscan2
- IQSEC2 | c.2833G>A p.D945N (on ENST00000642864 / NM_001111125.3; = p.D740N on NM_015075.2) | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs781977015; called by muse, varscan2
- KANK4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 179/383 reads (47%) | catalogued as rs1311359487, COSV62985750; called by muse, mutect2, varscan2
- KAZN | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 168/368 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430957481; called by muse, mutect2, varscan2
- KCNT1 | c.727C>T p.R243W (on ENST00000488444; = p.R262W on NM_020822.3) | Missense Mutation (SNP) | VAF 149/507 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs375711140; called by muse, mutect2, varscan2
- KIF14 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435446065, COSV100950704; called by muse, mutect2, varscan2
- KIF4B | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 218/476 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200320925; called by muse, mutect2, varscan2
- KIT | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.458); catalogued as rs200950545, COSV55388186, COSV55389759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL17 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 222/503 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV58530694; called by muse, mutect2
- KREMEN1 | c.113C>T p.A38V (on ENST00000407188; = p.A40V on NM_032045.5) | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs749531697; called by muse, mutect2, varscan2
- KRT18 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 315/533 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs746898922, COSV101184077; called by muse, mutect2, varscan2
- KRT24 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs147201922; called by muse, mutect2, varscan2
- KRT86 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 423/1193 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs376573652; called by muse, mutect2, varscan2
- LAP3 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 70/76 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441242027; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 132/250 reads (53%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LDB3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1410128172, COSV53951568; ClinVar: uncertain significance; called by muse, mutect2
- LINGO1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs973565369, COSV99051366; called by muse, mutect2, varscan2
- LINGO4 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 165/308 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759160503; called by muse, mutect2, varscan2
- LMBR1L | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs758249833, COSV57266924; called by muse, mutect2, varscan2
- MAP10 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 180/349 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV69364043; called by muse, mutect2, varscan2
- MAP1B | c.5901dup p.E1968Rfs*8 | Frame Shift Ins (INS) | VAF 66/174 reads (38%) | catalogued as rs775893760; called by mutect2, varscan2
- MAP3K20 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748593233, COSV64379442; called by muse, mutect2, varscan2
- MAPRE3 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51869188; called by muse, mutect2, varscan2
- MAST3 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs755807326, COSV53222737; called by muse, mutect2, varscan2
- MATN1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs377079004, COSV65651494; called by muse, mutect2, varscan2
- MCM3AP | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs762900381, COSV52436741; called by muse, mutect2, varscan2
- MDN1 | c.15157G>A p.A5053T | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs114504442; called by muse, mutect2, varscan2
- MEN1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 195/404 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770368608; called by muse, mutect2, varscan2
- MFAP1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1427724015, COSV51040268; called by muse, mutect2, varscan2
- MIDEAS | c.2162+1G>A p.X721_splice | Splice Site (SNP) | VAF 165/165 reads (100%) | catalogued as COSV54098394; called by muse, mutect2, varscan2
- MRPL14 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1274184499; called by muse, mutect2, varscan2
- MTMR8 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs756598274, COSV66392809; called by muse, mutect2, varscan2
- MTMR8 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs761484044, COSV66396493; called by muse, mutect2, varscan2
- MUS81 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768086876, COSV57259687; called by muse, mutect2, varscan2
- MYH11 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 48/930 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192001129; called by muse, mutect2
- MYH14 | c.929del p.G310Afs*21 | Frame Shift Del (DEL) | VAF 260/705 reads (37%) | catalogued as rs777112799; called by mutect2, pindel, varscan2
- MYH14 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 148/658 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51831991; called by muse, mutect2, varscan2
- MYH2 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 419/855 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs373108053; ClinVar: uncertain significance; called by muse, varscan2
- MYH7B | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 114/206 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs371539151; called by muse, mutect2, varscan2
- MYH8 | c.4297C>T p.L1433F | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV101238307, COSV67965336; called by muse, mutect2
- MYO16 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51795545; called by muse, mutect2, varscan2
- MYO19 | c.2794C>T p.R932W (on ENST00000614623 / NM_001163735.1; = p.R732W on NM_025109.5) | Missense Mutation (SNP) | VAF 118/236 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs765344804; called by muse, mutect2, varscan2
- MYT1 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 143/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60508209; called by muse, mutect2, varscan2
- NCAN | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 171/352 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs777412280; called by muse, mutect2, varscan2
- NF1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 155/340 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350329837, COSV100645963, COSV62225453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSMF | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 573/886 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); catalogued as rs201458494; called by muse, mutect2, varscan2
- NUAK1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 167/531 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs768508553; called by muse, mutect2, varscan2
- NUCB2 | c.1255+1G>A p.X419_splice | Splice Site (SNP) | VAF 94/200 reads (47%) | catalogued as rs1187794158; called by muse, mutect2, varscan2
- NUP62 | c.1339A>G p.M447V | Missense Mutation (SNP) | VAF 397/1710 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs748278801; called by muse, mutect2, varscan2
- OBSCN | c.9638C>T p.A3213V | Missense Mutation (SNP) | VAF 226/483 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.49); catalogued as rs375877740, COSV52758076; called by muse, mutect2, varscan2
- OCA2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 224/535 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs774460527; called by muse, mutect2, varscan2
- OCLN | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 322/644 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs539541122; called by muse, mutect2, varscan2
- PCARE | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 203/452 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756152942; called by muse, mutect2, varscan2
- PCDHA10 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 494/1095 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as rs782398517, COSV100254313; called by muse, mutect2
- PCDHA6 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 209/514 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65344724; called by muse, mutect2, varscan2
- PCDHA7 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 268/593 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65343037; called by muse, mutect2, varscan2
- PCDHB11 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 191/450 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1279523909, COSV61312727; called by muse, mutect2, varscan2
- PCSK5 | c.3738dup p.C1247Mfs*13 | Frame Shift Ins (INS) | VAF 64/276 reads (23%) | catalogued as rs1446950988; called by mutect2, pindel, varscan2
- PDCD11 | c.1486_1488del p.K496del | In Frame Del (DEL) | VAF 155/342 reads (45%) | catalogued as rs763827025; called by pindel, varscan2
- PDE4D | c.1999G>A p.V667M (on ENST00000340635 / NM_001104631.2; = p.V531M on NM_006203.4) | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs371593645; called by muse, mutect2, varscan2
- PDE4DIP | c.3244G>A p.V1082M | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV57700738; called by muse, mutect2, varscan2
- PDPK1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1378928701, COSV51913829; called by muse, mutect2, varscan2
- PELP1 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs376346386; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 70/160 reads (44%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PGAP1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs572676406; called by muse, mutect2, varscan2
- PHKA1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868926138, COSV59805391; called by muse, mutect2
- PI4KA | c.4630G>A p.V1544M | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs201391035; called by muse, mutect2, varscan2
- PIEZO2 | c.5888G>A p.R1963Q | Missense Mutation (SNP) | VAF 111/207 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs1480686209; called by muse, mutect2, varscan2
- PIK3C2A | c.5045C>T p.A1682V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs201133316, COSV56404414; called by muse, mutect2
- PLCD3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 135/288 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as rs1361449264; called by muse, mutect2, varscan2
- PLCG1 | c.3802G>A p.A1268T (on ENST00000373271 / NM_182811.2; = p.A1269T on NM_002660.3) | Missense Mutation (SNP) | VAF 113/220 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs761191435, COSV54820536; called by muse, mutect2, varscan2
- PLCL1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs140990771; called by muse, mutect2, varscan2
- PLXNC1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 243/402 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs748183392, COSV99313387; called by muse, mutect2, varscan2
- POU3F4 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 180/387 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs1250947545, COSV64539151; called by muse, mutect2, varscan2
- PPARGC1B | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 152/306 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754859721, COSV58528754; called by muse, mutect2, varscan2
- PPIL1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 268/609 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs775079812; called by muse, mutect2, varscan2
- PPP6R2 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs377314097; called by muse, mutect2, varscan2
- PRPF6 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 357/1202 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs757991297, COSV53866068; called by muse, mutect2, varscan2
- PRSS55 | c.141del p.S48Afs*36 | Frame Shift Del (DEL) | VAF 63/171 reads (37%) | catalogued as rs1404413098; called by mutect2, pindel, varscan2
- PSMC2 | c.423C>T p.G141= | Splice Region (SNP) | VAF 67/166 reads (40%) | catalogued as rs770391778; called by muse, mutect2, varscan2
- PTPRF | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs749276357; called by muse, mutect2
- PUF60 | c.914C>T p.P305L (on ENST00000526683 / NM_001362896.2; = p.P288L on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/384 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1309059867, COSV57592850; called by muse, mutect2, varscan2
- RAB22A | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174158375; called by muse, mutect2, varscan2
- RAB27A | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 242/485 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773233108, COSV61014510, COSV61017729; called by muse, mutect2, varscan2
- RAP1GAP | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs563762085; called by muse, mutect2
- RAPGEF6 | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373182124; called by muse, mutect2, varscan2
- RBBP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 166/406 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV58112735; called by muse, mutect2, varscan2
- RBL2 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263233694; called by muse, mutect2, varscan2
- RBM11 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759324505; called by muse, mutect2, varscan2
- RBM19 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 414/636 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs767542752, COSV55701210; called by muse, mutect2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 48/106 reads (45%) | catalogued as rs751690893; called by mutect2, varscan2
- RBMX | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1442643187; called by muse, mutect2
- RBMXL3 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 242/488 reads (50%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.094); catalogued as rs1556556197, COSV57759976; called by muse, mutect2, varscan2
- RCN1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs764118547, COSV50014326; called by muse, mutect2, varscan2
- RCOR3 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 160/365 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as rs1350236018, COSV65365749; called by muse, mutect2, varscan2
- RHBDD3 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 156/320 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1367170739; called by muse, mutect2, varscan2
- RHOXF1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54294358; called by muse, mutect2, varscan2
- ROGDI | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 153/316 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs751703075; called by muse, mutect2, varscan2
- RPGRIP1L | c.3576A>C p.K1192N | Missense Mutation (SNP) | VAF 130/255 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50909228; called by muse, mutect2, varscan2
- RPL7 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV53582045, COSV53582105; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 96/194 reads (49%) | catalogued as rs756606313; called by mutect2, varscan2
- RYR1 | c.2923C>T p.R975W | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371278145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.11075C>T p.A3692V | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100771943; called by muse, mutect2, varscan2
- SALL3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV73306074; called by mutect2, varscan2
- SBNO1 | c.3850G>A p.G1284S (on ENST00000420886; = p.G1283S on NM_018183.5) | Missense Mutation (SNP) | VAF 141/268 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs761076675; called by muse, mutect2, varscan2
- SCN5A | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs199473084, CM097628; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SEC14L5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750893044, COSV52037622; called by muse, mutect2, varscan2
- SEMA6C | c.2575G>C p.A859P | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.203); catalogued as rs762830558, COSV59004098; called by muse, varscan2
- SERHL2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 96/429 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs760043089; called by muse, mutect2, varscan2
- SETD1A | c.4792G>A p.V1598M | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52680586; called by muse, mutect2, varscan2
- SFTPB | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 31/828 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1442866526, COSV100667314; called by muse, mutect2
- SHFL | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 134/268 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs1456250797; called by muse, mutect2, varscan2
- SIPA1L1 | c.2869C>T p.R957* | Nonsense Mutation (SNP) | VAF 147/155 reads (95%) | catalogued as COSV62169373; called by muse, mutect2, varscan2
- SLC12A5 | c.2894G>A p.R965Q (on ENST00000454036 / NM_001134771.2; = p.R942Q on NM_020708.5) | Missense Mutation (SNP) | VAF 139/331 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.242); catalogued as rs760046175; called by muse, mutect2, varscan2
- SLC16A3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 299/625 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs781598860, COSV66430214; called by muse, mutect2, varscan2
- SLC66A1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 133/248 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs756272440, COSV100913177; called by muse, mutect2, varscan2
- SLIT3 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.219); catalogued as rs138617707; called by muse, mutect2, varscan2
- SMARCA4 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 325/650 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1401056652; called by muse, mutect2, varscan2
- SMG1 | c.7037C>T p.T2346M | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs781293265, COSV67170758, COSV67173346; called by muse, mutect2, varscan2
- SMG7 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1348069150, COSV61631567; called by muse, mutect2, varscan2
- SMPD3 | c.1646-3dup | Splice Region (INS) | VAF 68/164 reads (41%) | catalogued as rs759774779; called by mutect2, varscan2
- SNTG2 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs567924207, COSV57969357; called by muse, mutect2, varscan2
- SNX18 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.355); catalogued as COSV57992098; called by muse, mutect2, varscan2
- SPAAR | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 154/154 reads (100%) | PolyPhen benign (0.34); catalogued as rs899379535; called by muse, mutect2, varscan2
- SPDYE5 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 193/459 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1213080392; called by muse, mutect2, varscan2
- SPEG | c.8540G>A p.R2847Q | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs560447047, COSV56669202; called by muse, mutect2, varscan2
- SPPL2C | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 109/213 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs759534395; called by muse, mutect2, varscan2
- SSC4D | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs1455559504; called by muse, mutect2, varscan2
- ST20 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs778309866; called by muse, mutect2, varscan2
- ST3GAL3 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 214/488 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99495621; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.333del p.T112Pfs*11 | Frame Shift Del (DEL) | VAF 126/361 reads (35%) | catalogued as rs770458037; called by mutect2, pindel, varscan2
- STK10 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs375820809; called by muse, mutect2
- STK36 | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 212/434 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs144654930; called by muse, mutect2, varscan2
- STK36 | c.3431G>A p.R1144H | Missense Mutation (SNP) | VAF 157/310 reads (51%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.899); catalogued as rs202055753; called by muse, mutect2, varscan2
- STK39 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 170/362 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs201684592, COSV63593979; called by muse, mutect2, varscan2
- STRADA | c.947G>A p.R316H (on ENST00000336174 / NM_001363786.1; = p.R279H on NM_153335.6) | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1305201887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STRN4 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 122/244 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1568390270, COSV54422331; called by muse, mutect2, varscan2
- STXBP2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 231/532 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs140745219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 165/321 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs748419749; called by muse, mutect2, varscan2
- TAF9B | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782117490; called by muse, mutect2, varscan2
- TANC2 | c.4006C>T p.R1336C | Missense Mutation (SNP) | VAF 124/258 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1396830120; called by muse, varscan2
- TEDC1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs372232345; called by muse, mutect2, varscan2
- TENM2 | c.5464C>T p.R1822C (on ENST00000518659 / NM_001122679.2; = p.R1583C on NM_001080428.3) | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318739131, COSV69122789; called by muse, mutect2, varscan2
- TFRC | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 111/275 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs745484177; called by muse, mutect2, varscan2
- TLE2 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs766498805; called by muse, mutect2, varscan2
- TLE3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as rs756487725; called by muse, mutect2, varscan2
- TMEM104 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.303); catalogued as rs770423788; called by muse, mutect2
- TMEM38A | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754662236, COSV51818067, COSV51819543; called by muse, mutect2, varscan2
- TMEM68 | c.965G>A p.R322H (on ENST00000434581 / NM_001363177.1; = p.R255H on NM_152417.3) | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58169705; called by muse, mutect2, varscan2
- TMEM91 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as rs370880269; called by muse, mutect2, varscan2
- TMEM92 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 138/275 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV100305205, COSV55946304; called by muse, mutect2, varscan2
- TMTC3 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 163/290 reads (56%) | catalogued as COSV57124709; called by muse, mutect2, varscan2
- TNFRSF25 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 154/320 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs369890106; called by muse, mutect2, varscan2
- TNPO2 | c.2350C>T p.R784C (on ENST00000425528 / NM_001382240.1; = p.R774C on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/327 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790430; called by muse, mutect2, varscan2
- TPD52L1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs772348702, COSV59191130; called by muse, mutect2, varscan2
- TRAF4 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 231/573 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs145321614; called by muse, mutect2, varscan2
- TRAF7 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 154/338 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV58213894, COSV58215141, COSV58216343; called by muse, mutect2, varscan2
- TRIM66 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758937495; called by muse, mutect2, varscan2
- TRIR | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 234/474 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1306258758, COSV54406570; called by muse, mutect2, varscan2
- TRPC3 | c.271C>T p.R91W (on ENST00000379645 / NM_001366479.2; = p.R18W on NM_003305.2) | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53377890; called by muse, mutect2, varscan2
- TSPYL2 | c.249del p.I84Sfs*63 | Frame Shift Del (DEL) | VAF 50/94 reads (53%) | catalogued as rs1556807263; called by mutect2, varscan2
- TTN | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs150954246, COSV60095193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWNK | c.1592+5C>T | Splice Region (SNP) | VAF 211/486 reads (43%) | catalogued as rs1011909627; called by muse, mutect2, varscan2
- UGT1A6 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 208/454 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333719360, COSV59391983; called by muse, mutect2, varscan2
- UNC80 | c.2701G>A p.V901I | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.109); catalogued as rs146821032; called by muse, mutect2, varscan2
- UNC80 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 135/256 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1306650540, COSV99779173; called by muse, mutect2, varscan2
- UQCR11 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs773886090; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 24/43 reads (56%) | catalogued as rs762976381; called by mutect2, varscan2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 103/254 reads (41%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VWA2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 176/380 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs142413003; called by muse, mutect2, varscan2
- WASHC2C | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 122/339 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554861151; called by muse, mutect2, varscan2
- WSCD2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 519/857 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs950568945, COSV54585750; called by muse, mutect2, varscan2
- ZBTB20 | c.680C>T p.T227M (on ENST00000474710 / NM_001164342.2; = p.T154M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/210 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV61845502; called by muse, mutect2, varscan2
- ZNF253 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs764373867, COSV63037856; called by muse, mutect2, varscan2
- ZNF318 | c.3580C>T p.R1194W | Missense Mutation (SNP) | VAF 174/362 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209398200; called by muse, mutect2, varscan2
- ZNF536 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as rs761513607; called by muse, mutect2, varscan2
- ZNF609 | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 179/366 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361713145; called by muse, mutect2, varscan2
- ABCC8 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ADGRG6 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AFF3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 17/569 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2
- ALPG | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 237/612 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD46 | c.5_7del p.S2del | In Frame Del (DEL) | VAF 64/144 reads (44%) | called by mutect2, pindel
- ARID4A | c.3536A>G p.N1179S | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); called by muse, mutect2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 71/140 reads (51%) | called by mutect2, varscan2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 137/316 reads (43%) | called by mutect2, pindel, varscan2
- BMP7 | c.885del p.S296Afs*72 | Frame Shift Del (DEL) | VAF 342/858 reads (40%) | called by mutect2, pindel, varscan2
- BRWD1 | c.6766G>A p.E2256K | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- C19orf84 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2
- C4orf54 | c.1010del p.G337Efs*39 | Frame Shift Del (DEL) | VAF 62/149 reads (42%) | called by mutect2, pindel, varscan2
- C7 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CABLES1 | c.1342+1G>A p.X448_splice (on ENST00000256925 / NM_001100619.2; = p.X183_splice on NM_138375.2) | Splice Site (SNP) | VAF 63/137 reads (46%) | called by muse, mutect2, varscan2
- CACNA1F | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 178/417 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1S | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 158/455 reads (35%) | called by muse, mutect2
- CARD18 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CBFA2T2 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBR1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 135/271 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC186 | c.487_489del p.L163del | In Frame Del (DEL) | VAF 28/215 reads (13%) | called by pindel, varscan2
- CCDC188 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CD5L | c.672dup p.K225Efs*7 | Frame Shift Ins (INS) | VAF 85/233 reads (36%) | called by mutect2, pindel, varscan2
- CD93 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CDA | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 194/442 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CDA | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.38); called by muse, mutect2
- CHD6 | c.3392A>G p.E1131G | Missense Mutation (SNP) | VAF 235/464 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLDN22 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 207/417 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL5A1 | c.4085del p.P1362Lfs*126 | Frame Shift Del (DEL) | VAF 169/641 reads (26%) | called by mutect2, pindel, varscan2
- CORO1A | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 213/470 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CPEB1 | c.123del p.F41Lfs*10 | Frame Shift Del (DEL) | VAF 75/201 reads (37%) | called by mutect2, pindel, varscan2
- CSAD | c.487G>A p.A163T (on ENST00000444623 / NM_001244705.2; = p.A190T on NM_015989.5) | Missense Mutation (SNP) | VAF 428/690 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTDSPL | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DCHS2 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- DCUN1D4 | c.826C>T p.P276S (on ENST00000334635 / NM_001287757.1; = p.P241S on NM_015115.3) | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- DIS3L2 | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 314/643 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DLG5 | c.2237G>T p.G746V | Missense Mutation (SNP) | VAF 133/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ESM1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 110/243 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM193B | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- FBXO33 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FEM1C | c.778dup p.R260Kfs*20 | Frame Shift Ins (INS) | VAF 89/182 reads (49%) | called by mutect2, varscan2
- FOXO1 | c.1730del p.G577Afs*5 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- FOXO6 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT tolerated (0.78); called by muse, mutect2, varscan2
- FRMD7 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 209/463 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABARAPL2 | c.33G>A p.L11= | Splice Region (SNP) | VAF 137/331 reads (41%) | called by muse, mutect2, varscan2
- GAREM2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GJA8 | c.1214G>A p.C405Y | Missense Mutation (SNP) | VAF 256/569 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLRX2 | c.472del p.S158Vfs*22 (on ENST00000367439 / NM_197962.3; = p.S159Vfs*22 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 50/87 reads (57%) | called by mutect2, varscan2
- GLYATL1 | c.394C>A p.L132I (on ENST00000317391 / NM_001354699.1; = p.L163I on NM_080661.4) | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GUCY2D | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- HDAC1 | c.1277_1279del p.E426del | In Frame Del (DEL) | VAF 32/76 reads (42%) | called by pindel, varscan2
- HDAC2 | c.1375dup p.T459Nfs*4 | Frame Shift Ins (INS) | VAF 33/63 reads (52%) | called by mutect2, varscan2
- HERC1 | c.10912G>T p.G3638C | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFI16 | c.2297dup p.N766Kfs*9 (on ENST00000295809 / NM_001364867.2; = p.N710Kfs*9 on NM_005531.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- IGSF3 | c.2275C>T p.H759Y (on ENST00000369486 / NM_001007237.3; = p.H779Y on NM_001542.4) | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- INCENP | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- JPH3 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 185/424 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KANSL3 | c.2426C>T p.A809V (on ENST00000666923 / NM_001349262.2; = p.A783V on NM_001115016.3) | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2
- KCNK17 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- KDR | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 154/387 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIAA1522 | c.1749dup p.S584Lfs*14 (on ENST00000373480 / NM_001198972.2; = p.S643Lfs*14 on NM_020888.3) | Frame Shift Ins (INS) | VAF 64/210 reads (30%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.1643G>A p.C548Y | Missense Mutation (SNP) | VAF 82/106 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- KIF21A | c.2305dup p.T769Nfs*20 (on ENST00000361418 / NM_001378440.1; = p.T756Nfs*20 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 104/194 reads (54%) | called by mutect2, varscan2
- KLHL1 | c.764T>G p.M255R | Missense Mutation (SNP) | VAF 115/228 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LCP2 | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LETM1 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- LRCH2 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC38 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.147); called by muse, mutect2
- LRRC70 | c.1325G>A p.S442N | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRSAM1 | c.1698+2_1698+5del p.X566_splice | Splice Site (DEL) | VAF 336/621 reads (54%) | called by mutect2, pindel, varscan2
- MAF | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2
- MAZ | c.413del p.P138Rfs*28 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- MDN1 | c.12478C>T p.H4160Y | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.123); called by muse, mutect2
- MIB1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MID1 | c.1856A>T p.D619V | Missense Mutation (SNP) | VAF 287/644 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MIGA1 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIGA1 | c.1188+10del | Splice Region (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- MPP5 | c.60_63del p.N20Kfs*27 | Frame Shift Del (DEL) | VAF 8/89 reads (9%) | called by mutect2, pindel
- MSLN | c.1300G>A p.D434N (on ENST00000382862 / NM_013404.4; = p.D426N on NM_005823.6) | Missense Mutation (SNP) | VAF 140/379 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.067); called by muse, varscan2
- MSN | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 82/145 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1 | c.1473C>A p.C491* | Nonsense Mutation (SNP) | VAF 262/408 reads (64%) | called by muse, varscan2
- NADK | c.22dup p.M8Nfs*5 | Frame Shift Ins (INS) | VAF 91/248 reads (37%) | called by mutect2, pindel, varscan2
- NBEA | c.6747dup p.V2250Sfs*4 | Frame Shift Ins (INS) | VAF 70/152 reads (46%) | called by mutect2, varscan2
- NDC80 | c.1438del p.M480Wfs*7 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- NEMF | c.3154-3del | Splice Region (DEL) | VAF 72/78 reads (92%) | called by mutect2, varscan2
- NF1 | c.5812+6T>C | Splice Region (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- NFE2L2 | c.827_828del p.T276Sfs*7 | Frame Shift Del (DEL) | VAF 59/214 reads (28%) | called by pindel, varscan2
- NISCH | c.765+2T>C p.X255_splice | Splice Site (SNP) | VAF 82/164 reads (50%) | called by muse, mutect2, varscan2
- NR2F2 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 209/459 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRXN2 | c.2035del p.A679Lfs*13 | Frame Shift Del (DEL) | VAF 74/186 reads (40%) | called by mutect2, pindel, varscan2
- NSD2 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 69/69 reads (100%) | called by muse, mutect2, varscan2
- OBSCN | c.9178T>G p.Y3060D | Missense Mutation (SNP) | VAF 222/442 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OBSCN | c.23074_23076del p.K7692del | In Frame Del (DEL) | VAF 77/167 reads (46%) | called by mutect2, pindel, varscan2
- OFD1 | c.1310_1312del p.Y437del | In Frame Del (DEL) | VAF 50/139 reads (36%) | called by pindel, varscan2
- OPN1LW | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 269/610 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PHTF2 | c.1877G>A p.R626Q (on ENST00000248550 / NM_001366089.1; = p.R588Q on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- PIH1D1 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 188/431 reads (44%) | called by muse, mutect2, varscan2
- PLCG2 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLPPR3 | c.1547G>A p.R516H (on ENST00000520876 / NM_001270366.2; = p.R544H on NM_024888.2) | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PML | c.138del p.A47Lfs*51 | Frame Shift Del (DEL) | VAF 155/408 reads (38%) | called by mutect2, pindel, varscan2
- PPFIA1 | c.1315dup p.M439Nfs*6 | Frame Shift Ins (INS) | VAF 56/158 reads (35%) | called by mutect2, pindel, varscan2
- PPP1R12C | c.1116del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 35/50 reads (70%) | called by mutect2, pindel, varscan2
- PRPF4B | c.2340del p.K780Nfs*13 | Frame Shift Del (DEL) | VAF 76/150 reads (51%) | called by mutect2, varscan2
- PSMD1 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTGFR | c.97del p.S33Qfs*2 | Frame Shift Del (DEL) | VAF 116/296 reads (39%) | called by mutect2, pindel, varscan2
- RAD50 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 22/736 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, varscan2
- RAMP2 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 143/286 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RNASEH2C | c.262_264del p.E88del | In Frame Del (DEL) | VAF 227/548 reads (41%) | called by mutect2, pindel, varscan2
- RNF19A | c.187del p.R63Efs*5 | Frame Shift Del (DEL) | VAF 109/279 reads (39%) | called by mutect2, pindel, varscan2
- SALL4 | c.2804T>C p.I935T | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- SBF1 | c.5167C>T p.L1723F | Missense Mutation (SNP) | VAF 138/310 reads (45%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCPEP1 | c.273dup p.G92Wfs*4 | Frame Shift Ins (INS) | VAF 170/435 reads (39%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 200/766 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6A | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 23/339 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 37/134 reads (28%) | called by mutect2, varscan2
- SETD1B | c.4765del p.Q1589Sfs*11 | Frame Shift Del (DEL) | VAF 72/156 reads (46%) | called by mutect2, pindel, varscan2
- SH2D3A | c.134del p.G45Afs*4 | Frame Shift Del (DEL) | VAF 88/250 reads (35%) | called by mutect2, pindel, varscan2
- SIK2 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A7 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 36/698 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC39A7 | c.696_698del p.V233del | In Frame Del (DEL) | VAF 46/165 reads (28%) | called by mutect2, pindel*, varscan2
- SLC44A1 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 17/379 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SLC45A4 | c.2398dup p.I800Nfs*13 (on ENST00000517878 / NM_001286646.2; = p.F747Ifs*10 on NM_001080431.2) | Frame Shift Ins (INS) | VAF 47/124 reads (38%) | called by mutect2, varscan2
- SMC3 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SPTBN5 | c.2925G>T p.Q975H | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SSH1 | c.1519del p.L507Sfs*62 | Frame Shift Del (DEL) | VAF 183/372 reads (49%) | called by mutect2, pindel, varscan2
- ST3GAL1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 116/270 reads (43%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TAF1D | c.483del p.F161Lfs*7 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel
- TBX19 | c.545_564del p.T182Nfs*12 | Frame Shift Del (DEL) | VAF 188/618 reads (30%) | called by pindel, varscan2
- THOP1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 145/320 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TMEM164 | c.454A>G p.M152V (on ENST00000372068 / NM_032227.4; = p.M3V on NM_017698.2) | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.229); called by muse, mutect2
- TNFSF11 | c.825A>G p.I275M | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- TRAF3IP1 | c.768del p.E258Rfs*5 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- TSGA10 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TYK2 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UBXN4 | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 118/232 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UPF3B | c.1339C>T p.R447* (on ENST00000276201 / NM_080632.3; = p.R434* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 212/432 reads (49%) | called by muse, mutect2, varscan2
- USH1C | c.1425del p.I476Lfs*22 | Frame Shift Del (DEL) | VAF 230/692 reads (33%) | called by pindel, varscan2
- USP30 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); called by muse, mutect2
- USP48 | c.2520_2521del p.C841Sfs*17 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by pindel, varscan2
- UTP3 | c.774del p.G259Efs*7 | Frame Shift Del (DEL) | VAF 68/191 reads (36%) | called by mutect2, pindel, varscan2
- VPS13C | c.4996G>A p.G1666R (on ENST00000644861 / NM_020821.3; = p.G1623R on NM_017684.5) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- VWA1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 121/226 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WT1 | c.508T>A p.S170T | Missense Mutation (SNP) | VAF 310/672 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZAP70 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 192/393 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ZFHX3 | c.1945C>A p.L649M | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX4 | c.6170del p.P2057Hfs*26 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, varscan2
- ZNF226 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 125/235 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF280C | c.1808dup p.N603Kfs*2 | Frame Shift Ins (INS) | VAF 74/181 reads (41%) | called by mutect2, pindel, varscan2
- ZNF34 | c.747del p.K249Nfs*75 | Frame Shift Del (DEL) | VAF 99/285 reads (35%) | called by mutect2, pindel, varscan2
- ZNF578 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF726 | c.1637_1638del p.F546* | Frame Shift Del (DEL) | VAF 160/372 reads (43%) | called by mutect2, pindel, varscan2
- ZNF862 | c.2304G>T p.Q768H | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); called by muse, mutect2
- ABCB9 | c.507G>A p.A169= | Silent (SNP) | VAF 31/576 reads (5%) | catalogued as rs773139795, COSV99757907; called by muse, mutect2
- ABHD17A | c.90G>A p.P30= | Silent (SNP) | VAF 175/378 reads (46%) | catalogued as rs1436301012, COSV99171193; called by mutect2, varscan2
- ADGRB1 | c.2025C>T p.D675= | Silent (SNP) | VAF 67/182 reads (37%) | catalogued as rs367986539; called by muse, mutect2, varscan2
- AFG3L2 | c.1386G>A p.A462= | Silent (SNP) | VAF 340/762 reads (45%) | catalogued as COSV52316873; called by muse, mutect2, varscan2
- ALPG | c.1269C>T p.G423= | Silent (SNP) | VAF 85/189 reads (45%) | called by muse, mutect2, varscan2
- ALPP | c.1278C>T p.G426= | Silent (SNP) | VAF 110/737 reads (15%) | catalogued as COSV67397178, COSV67398338; called by muse, mutect2, varscan2
- ANKRD11 | c.7749C>T p.N2583= | Silent (SNP) | VAF 341/714 reads (48%) | catalogued as rs138161949; called by muse, mutect2, varscan2
- ANKRD27 | c.2358G>A p.Q786= | Silent (SNP) | VAF 177/195 reads (91%) | called by muse, mutect2, varscan2
- APBA1 | c.504C>T p.Y168= | Silent (SNP) | VAF 209/581 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.996C>T p.Y332= | Silent (SNP) | VAF 186/375 reads (50%) | catalogued as rs782314375, COSV53639264; called by muse, mutect2, varscan2
- ATP10A | c.2607C>T p.D869= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as rs372023252; called by muse, mutect2, varscan2
- ATP1A2 | c.2079G>A p.Q693= | Silent (SNP) | VAF 364/775 reads (47%) | catalogued as rs1387493049; called by muse, mutect2, varscan2
- BACH2 | c.624C>T p.P208= | Silent (SNP) | VAF 137/258 reads (53%) | catalogued as rs991761443, COSV57608526; called by muse, mutect2, varscan2
- BCL11B | c.2241C>T p.N747= (on ENST00000357195 / NM_001282237.2; = p.N676= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 217/217 reads (100%) | called by muse, mutect2, varscan2
- BCL2L11 | c.405G>A p.R135= (on ENST00000393256 / NM_138621.5; = p.R75= on NM_006538.5) | Silent (SNP) | VAF 96/211 reads (45%) | called by muse, mutect2, varscan2
- BEND3 | c.2349C>T p.Y783= | Silent (SNP) | VAF 199/434 reads (46%) | catalogued as rs541825404; called by muse, mutect2, varscan2
- BEST4 | c.42C>T p.F14= | Silent (SNP) | VAF 158/359 reads (44%) | catalogued as rs754871004, COSV64734573; called by muse, mutect2, varscan2
- BOP1 | c.1614G>A p.T538= | Silent (SNP) | VAF 307/691 reads (44%) | catalogued as rs1221188898; called by muse, mutect2, varscan2
- BSN | c.10584C>T p.C3528= | Silent (SNP) | VAF 83/227 reads (37%) | catalogued as rs1213710998; called by muse, mutect2, varscan2
- BZW1 | c.1119C>T p.S373= | Silent (SNP) | VAF 94/187 reads (50%) | catalogued as rs527916518; called by muse, mutect2, varscan2
- CBX6 | c.930G>A p.P310= | Silent (SNP) | VAF 190/365 reads (52%) | catalogued as rs771912988; called by muse, mutect2, varscan2
- CBX7 | c.726C>A p.G242= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as rs1319175001; called by muse, mutect2, varscan2
- CCDC24 | c.183C>T p.S61= | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- CCDC3 | c.693G>A p.A231= | Silent (SNP) | VAF 281/525 reads (54%) | catalogued as rs763966247, COSV66558407, COSV66560237; called by muse, mutect2, varscan2
- CFAP410 | c.403C>T p.L135= | Silent (SNP) | VAF 102/213 reads (48%) | called by muse, mutect2, varscan2
- CFLAR | c.1278C>T p.C426= | Silent (SNP) | VAF 75/132 reads (57%) | called by muse, mutect2, varscan2
- CHD5 | c.3813C>T p.D1271= | Silent (SNP) | VAF 129/247 reads (52%) | catalogued as rs201484104, COSV52422737; called by muse, mutect2, varscan2
- CHST8 | c.639C>T p.A213= | Silent (SNP) | VAF 141/141 reads (100%) | catalogued as rs987438640, COSV52860085; called by muse, mutect2, varscan2
- CLVS1 | c.921C>T p.H307= | Silent (SNP) | VAF 86/179 reads (48%) | catalogued as rs372058481; called by muse, mutect2, varscan2
- CNNM4 | c.1269C>T p.Y423= | Silent (SNP) | VAF 227/463 reads (49%) | catalogued as rs758866379, COSV65661123; called by muse, mutect2, varscan2
- CNTRL | c.1674C>T p.S558= | Silent (SNP) | VAF 47/162 reads (29%) | catalogued as rs1435556167; called by muse, mutect2, varscan2
- COL6A6 | c.3816A>T p.G1272= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV100651122; called by muse, mutect2
- CRB1 | c.1074C>A p.S358= | Silent (SNP) | VAF 213/409 reads (52%) | called by muse, mutect2, varscan2
- DAG1 | c.2205A>G p.E735= | Silent (SNP) | VAF 288/587 reads (49%) | called by muse, mutect2, varscan2
- DCHS1 | c.4173G>A p.A1391= | Silent (SNP) | VAF 13/275 reads (5%) | called by muse, mutect2
- DDX27 | c.1017G>A p.A339= | Silent (SNP) | VAF 103/222 reads (46%) | catalogued as rs1298000053; called by muse, mutect2, varscan2
- DENND2B | c.534G>A p.S178= | Silent (SNP) | VAF 180/427 reads (42%) | catalogued as COSV58201446; called by muse, mutect2, varscan2
- DHX57 | c.120C>T p.G40= | Silent (SNP) | VAF 122/281 reads (43%) | catalogued as rs772879942, COSV99770183; called by mutect2, varscan2
- DIDO1 | c.6C>T p.D2= | Silent (SNP) | VAF 51/75 reads (68%) | catalogued as rs59453100; called by muse, mutect2, varscan2
- DNAJB8 | c.270C>T p.G90= | Silent (SNP) | VAF 194/392 reads (49%) | called by muse, mutect2, varscan2
- DVL1 | c.1668G>A p.P556= (on ENST00000378888 / NM_001330311.2; = p.P531= on NM_004421.3) | Silent (SNP) | VAF 85/187 reads (45%) | catalogued as rs746715259; called by muse, mutect2, varscan2
- DVL1 | c.273G>A p.A91= | Silent (SNP) | VAF 160/335 reads (48%) | catalogued as rs201640020; called by muse, mutect2, varscan2
- EFCAB5 | c.1446T>C p.S482= | Silent (SNP) | VAF 73/174 reads (42%) | called by muse, mutect2, varscan2
- EFR3B | c.1998C>T p.G666= | Silent (SNP) | VAF 93/238 reads (39%) | called by muse, mutect2, varscan2
- EGR1 | c.1194C>T p.C398= | Silent (SNP) | VAF 228/522 reads (44%) | catalogued as rs200663508; called by muse, mutect2, varscan2
- ENTPD7 | c.186C>T p.Y62= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs374024141; called by muse, mutect2, varscan2
- EXT1 | c.987C>T p.H329= | Silent (SNP) | VAF 18/582 reads (3%) | catalogued as rs1369831625; called by muse, mutect2
- FAT1 | c.2574G>A p.T858= | Silent (SNP) | VAF 97/218 reads (44%) | catalogued as rs376884651; called by muse, mutect2, varscan2
- FCGRT | c.840G>A p.A280= | Silent (SNP) | VAF 369/737 reads (50%) | catalogued as rs768621432, COSV99571236; called by muse, mutect2, varscan2
- FGD4 | c.2217C>T p.V739= | Silent (SNP) | VAF 329/555 reads (59%) | called by muse, mutect2, varscan2
- FGFRL1 | c.1275C>T p.D425= | Silent (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
- FOXP4 | c.1515C>T p.R505= (on ENST00000307972 / NM_001012426.1; = p.R492= on NM_138457.3) | Silent (SNP) | VAF 134/295 reads (45%) | called by muse, mutect2, varscan2
- FZD1 | c.1731C>T p.Y577= | Silent (SNP) | VAF 116/202 reads (57%) | called by muse, mutect2, varscan2
- GABBR1 | c.252C>T p.N84= | Silent (SNP) | VAF 178/386 reads (46%) | catalogued as rs568472804, COSV63542674; called by muse, mutect2, varscan2
- GDF2 | c.1107G>A p.T369= | Silent (SNP) | VAF 79/207 reads (38%) | catalogued as rs1196442309; called by muse, mutect2, varscan2
- GMEB2 | c.72C>T p.D24= | Silent (SNP) | VAF 83/322 reads (26%) | catalogued as rs775670456, COSV56606206; called by muse, mutect2, varscan2
- GOLGA8N | c.1464C>T p.C488= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- GOLGA8R | c.1461C>T p.C487= | Silent (SNP) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- GPR157 | c.693G>A p.P231= | Silent (SNP) | VAF 103/262 reads (39%) | catalogued as rs137902270; called by muse, mutect2, varscan2
- GPR25 | c.1059C>T p.A353= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs552292157, COSV100421704; called by muse, mutect2, varscan2
- GRIA3 | c.936C>T p.D312= | Silent (SNP) | VAF 14/278 reads (5%) | catalogued as rs1348055128, COSV52075945; called by muse, mutect2
- GRK7 | c.51G>A p.L17= | Silent (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- GSPT2 | c.1356C>T p.S452= | Silent (SNP) | VAF 142/307 reads (46%) | catalogued as rs1557348951, COSV61214276; called by muse, mutect2, varscan2
- HGFAC | c.786C>T p.T262= | Silent (SNP) | VAF 108/109 reads (99%) | catalogued as rs746573048; called by muse, mutect2, varscan2
- HHIPL2 | c.2064C>T p.A688= | Silent (SNP) | VAF 262/629 reads (42%) | called by muse, mutect2, varscan2
- HIVEP3 | c.3207C>T p.S1069= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as rs538096073, COSV99912609; called by muse, mutect2, varscan2
- ICOS | c.570A>G p.K190= | Silent (SNP) | VAF 120/275 reads (44%) | called by muse, mutect2, varscan2
- IGSF9 | c.3519C>T p.P1173= (on ENST00000368094 / NM_001135050.2; = p.P1157= on NM_020789.4) | Silent (SNP) | VAF 239/505 reads (47%) | catalogued as rs748504173, COSV100231010; called by muse, mutect2, varscan2
- ILDR2 | c.1803C>T p.R601= | Silent (SNP) | VAF 131/231 reads (57%) | catalogued as rs765636434; called by muse, mutect2, varscan2
- INPP5D | c.1740G>A p.T580= (on ENST00000445964 / NM_001017915.3; = p.T579= on NM_005541.5) | Silent (SNP) | VAF 27/454 reads (6%) | catalogued as rs759745293, COSV64040664; called by muse, mutect2
- IRGQ | c.1515C>T p.D505= | Silent (SNP) | VAF 121/221 reads (55%) | catalogued as rs756048262; called by muse, mutect2, varscan2
- ISLR2 | c.234G>A p.T78= | Silent (SNP) | VAF 12/346 reads (3%) | catalogued as rs928629890; called by muse, mutect2
- ITGA5 | c.1806G>A p.S602= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs772385573, COSV53216451; called by muse, mutect2, varscan2
- ITLN1 | c.513G>A p.T171= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs142129957, COSV58275918; called by muse, mutect2, varscan2
- JARID2 | c.1188G>A p.A396= | Silent (SNP) | VAF 97/187 reads (52%) | catalogued as rs149943687; called by muse, mutect2, varscan2
- KCND3 | c.843C>T p.D281= | Silent (SNP) | VAF 172/359 reads (48%) | catalogued as rs1287255718, COSV56176900; called by muse, mutect2, varscan2
- KEAP1 | c.570C>T p.F190= | Silent (SNP) | VAF 209/417 reads (50%) | catalogued as COSV50640203; called by muse, mutect2, varscan2
- KRBA1 | c.2586C>T p.R862= | Silent (SNP) | VAF 163/333 reads (49%) | called by muse, mutect2, varscan2
- LMTK2 | c.3633C>T p.S1211= | Silent (SNP) | VAF 143/308 reads (46%) | catalogued as rs764356535; called by muse, mutect2, varscan2
- LPAR4 | c.846T>C p.N282= | Silent (SNP) | VAF 93/248 reads (38%) | called by muse, mutect2, varscan2
- MAP4K1 | c.642G>A p.P214= | Silent (SNP) | VAF 115/116 reads (99%) | catalogued as rs35922303; called by muse, mutect2, varscan2
- MCOLN1 | c.99G>A p.P33= | Silent (SNP) | VAF 243/452 reads (54%) | catalogued as rs760801246; called by muse, mutect2, varscan2
- MED8 | c.636G>A p.T212= | Silent (SNP) | VAF 279/660 reads (42%) | catalogued as rs776989822, COSV51939845; called by muse, mutect2, varscan2
- METTL22 | c.666C>T p.I222= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs530526653, COSV50837663; called by muse, mutect2
- MIB2 | c.561C>T p.H187= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs375686906; called by muse, mutect2, varscan2
- MICAL3 | c.2745C>T p.A915= | Silent (SNP) | VAF 229/497 reads (46%) | catalogued as rs761909172; called by muse, mutect2, varscan2
- MOGAT3 | c.888C>T p.P296= | Silent (SNP) | VAF 87/188 reads (46%) | catalogued as rs781425954, COSV56174058; called by muse, mutect2, varscan2
- MSH4 | c.168G>A p.T56= | Silent (SNP) | VAF 207/448 reads (46%) | catalogued as rs774095092, COSV54204248; called by muse, varscan2
- MTPAP | c.561C>T p.D187= | Silent (SNP) | VAF 179/390 reads (46%) | catalogued as rs747737059; called by muse, mutect2, varscan2
- MUC2 | c.3738C>T p.N1246= | Silent (SNP) | VAF 278/631 reads (44%) | catalogued as rs376760340; called by muse, varscan2
- MUC3A | c.8919G>A p.P2973= | Silent (SNP) | VAF 95/333 reads (29%) | catalogued as rs770825182, COSV60210171; called by muse, mutect2, varscan2
- MYL9 | c.261C>A p.L87= | Silent (SNP) | VAF 97/275 reads (35%) | called by muse, mutect2, varscan2
- MYO15A | c.2016C>T p.S672= | Silent (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- MYO16 | c.2721C>T p.Y907= | Silent (SNP) | VAF 97/175 reads (55%) | catalogued as rs751174402, COSV51788268; called by muse, mutect2, varscan2
- MYO1C | c.2046G>A p.T682= (on ENST00000648651 / NM_001080779.2; = p.T647= on NM_033375.5) | Silent (SNP) | VAF 381/777 reads (49%) | catalogued as rs757819967, COSV100704286; called by muse, mutect2, varscan2
- MYOD1 | c.519C>T p.G173= | Silent (SNP) | VAF 205/404 reads (51%) | called by muse, mutect2, varscan2
- NCEH1 | c.393G>A p.P131= (on ENST00000538775; = p.P99= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 254/544 reads (47%) | catalogued as rs149025248; called by muse, mutect2, varscan2
- NHLRC1 | c.729C>T p.D243= | Silent (SNP) | VAF 256/516 reads (50%) | catalogued as rs146420615; called by muse, mutect2, varscan2
- NRN1 | c.138C>T p.G46= | Silent (SNP) | VAF 105/238 reads (44%) | catalogued as COSV55205507; called by muse, mutect2, varscan2
- NUP107 | c.2049G>A p.A683= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as rs149594646; called by muse, mutect2, varscan2
- NUTM2E | c.1680G>A p.P560= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs773013947; called by mutect2, varscan2
- PABPC3 | c.36G>A p.S12= | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as COSV55799719; called by muse, mutect2, varscan2
- PARP8 | c.1143G>A p.S381= | Silent (SNP) | VAF 115/224 reads (51%) | catalogued as rs777257327, COSV55869140; called by muse, mutect2, varscan2
- PCDHA3 | c.708C>T p.N236= | Silent (SNP) | VAF 152/304 reads (50%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.711G>A p.A237= | Silent (SNP) | VAF 152/318 reads (48%) | catalogued as COSV53935044; called by muse, mutect2, varscan2
- PDILT | c.1632C>T p.Y544= | Silent (SNP) | VAF 297/572 reads (52%) | catalogued as rs374255958, COSV56701088; called by muse, mutect2, varscan2
- PDPR | c.765G>A p.P255= | Silent (SNP) | VAF 198/1014 reads (20%) | catalogued as rs1427698397; called by muse, varscan2
- PDZK1IP1 | c.30C>T p.G10= | Silent (SNP) | VAF 80/173 reads (46%) | catalogued as rs377640107; called by muse, mutect2, varscan2
- PEAK3 | c.255G>A p.P85= | Silent (SNP) | VAF 74/150 reads (49%) | catalogued as rs1000951796; called by muse, mutect2, varscan2
- PISD | c.660C>T p.G220= (on ENST00000439502 / NM_001326412.1; = p.G186= on NM_014338.3) | Silent (SNP) | VAF 118/274 reads (43%) | catalogued as rs754866362; called by muse, mutect2, varscan2
- PLEKHM1 | c.339G>A p.T113= | Silent (SNP) | VAF 272/576 reads (47%) | catalogued as rs764582224; called by muse, mutect2, varscan2
- PLP1 | c.342C>T p.S114= | Silent (SNP) | VAF 182/362 reads (50%) | catalogued as rs756334357; called by muse, mutect2, varscan2
- PLXND1 | c.3153C>T p.F1051= | Silent (SNP) | VAF 225/491 reads (46%) | catalogued as rs151241774; called by muse, mutect2, varscan2
- PPP2R3C | c.165C>T p.T55= | Silent (SNP) | VAF 45/49 reads (92%) | called by muse, mutect2, varscan2
- PRDM2 | c.4951C>A p.R1651= | Silent (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- PRPF6 | c.2802C>T p.A934= | Silent (SNP) | VAF 145/487 reads (30%) | catalogued as rs755778991, COSV53874009; called by muse, mutect2, varscan2
- PRSS38 | c.735C>T p.S245= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as rs369446054; called by muse, mutect2, varscan2
- PTPRU | c.2031C>A p.A677= | Silent (SNP) | VAF 286/591 reads (48%) | catalogued as rs1364723313; called by muse, mutect2, varscan2
- PXN | c.1137C>T p.P379= (on ENST00000228307 / NM_001080855.3; = p.P345= on NM_002859.4) | Silent (SNP) | VAF 290/431 reads (67%) | catalogued as rs754778377; called by muse, mutect2, varscan2
- RBM5 | c.216C>T p.S72= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as rs765156684; called by muse, mutect2, varscan2
- RNFT2 | c.243G>A p.S81= | Silent (SNP) | VAF 135/348 reads (39%) | catalogued as rs774198334; called by muse, mutect2, varscan2
- RUBCN | c.370C>T p.L124= | Silent (SNP) | VAF 187/375 reads (50%) | called by muse, mutect2, varscan2
- SAFB2 | c.2481C>T p.S827= | Silent (SNP) | VAF 102/228 reads (45%) | catalogued as rs769071549; called by muse, mutect2, varscan2
- SART1 | c.1176G>A p.T392= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- SELENBP1 | c.252C>T p.F84= | Silent (SNP) | VAF 96/210 reads (46%) | catalogued as rs761764152, COSV64373011; called by muse, mutect2, varscan2
- SHLD3 | c.102G>A p.P34= | Silent (SNP) | VAF 75/161 reads (47%) | catalogued as rs1285157985; called by muse, mutect2, varscan2
- SIN3A | c.3309G>A p.E1103= | Silent (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1059C>T p.D353= | Silent (SNP) | VAF 72/147 reads (49%) | catalogued as rs757351459, COSV53763683; called by muse, mutect2, varscan2
- SLC16A6 | c.417C>T p.I139= | Silent (SNP) | VAF 105/229 reads (46%) | called by muse, mutect2, varscan2
- SLC17A2 | c.1119C>T p.Y373= | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as rs773778901, COSV99614618; called by muse, mutect2, varscan2
- SLC22A23 | c.1365C>T p.H455= | Silent (SNP) | VAF 164/336 reads (49%) | catalogued as rs138000137; called by muse, mutect2, varscan2
- SLC7A6 | c.1146C>T p.I382= | Silent (SNP) | VAF 105/232 reads (45%) | catalogued as rs767868194; called by muse, mutect2, varscan2
- SLCO6A1 | c.75G>A p.A25= | Silent (SNP) | VAF 98/239 reads (41%) | catalogued as rs1440160929, COSV65806599; called by muse, mutect2, varscan2
- SLITRK5 | c.2160C>T p.G720= | Silent (SNP) | VAF 61/123 reads (50%) | catalogued as COSV61521388; called by muse, mutect2, varscan2
- SRL | c.705G>A p.E235= | Silent (SNP) | VAF 101/258 reads (39%) | called by muse, mutect2, varscan2
- SRMS | c.879G>A p.S293= | Silent (SNP) | VAF 107/416 reads (26%) | catalogued as rs756318161, COSV99420529; called by muse, mutect2, varscan2
- SRPK3 | c.1038G>A p.A346= | Silent (SNP) | VAF 192/384 reads (50%) | catalogued as rs376127813; called by muse, mutect2
- STAP2 | c.861G>A p.P287= | Silent (SNP) | VAF 64/116 reads (55%) | catalogued as rs145032917, COSV99696649; called by muse, mutect2
- SUN1 | c.1059G>A p.S353= (on ENST00000405266 / NM_001367651.1; = p.S233= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as rs776253918; called by muse, mutect2, varscan2
- SYAP1 | c.750C>T p.P250= | Silent (SNP) | VAF 119/289 reads (41%) | catalogued as COSV101204909; called by muse, mutect2, varscan2
- TBC1D31 | c.915C>T p.L305= | Silent (SNP) | VAF 175/393 reads (45%) | called by muse, mutect2, varscan2
- THRA | c.468G>A p.Q156= | Silent (SNP) | VAF 230/505 reads (46%) | called by muse, mutect2, varscan2
- THSD4 | c.939C>A p.I313= | Silent (SNP) | VAF 13/334 reads (4%) | called by muse, mutect2
- TMCO6 | c.837T>C p.H279= | Silent (SNP) | VAF 80/214 reads (37%) | catalogued as rs377210720; called by muse, mutect2, varscan2
- TMEM51 | c.402C>T p.Y134= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs748204095; called by muse, mutect2, varscan2
- TPST1 | c.1038T>A p.T346= | Silent (SNP) | VAF 82/183 reads (45%) | called by muse, varscan2
- TRABD2A | c.444C>T p.Y148= | Silent (SNP) | VAF 187/395 reads (47%) | catalogued as rs371560834; called by muse, mutect2, varscan2
- TRERF1 | c.129C>T p.G43= | Silent (SNP) | VAF 225/471 reads (48%) | catalogued as rs138805200; called by muse, varscan2
- TTC27 | c.2140C>T p.L714= | Silent (SNP) | VAF 33/394 reads (8%) | catalogued as COSV58656760; called by muse, mutect2
- USP27X | c.1080C>T p.N360= | Silent (SNP) | VAF 183/410 reads (45%) | catalogued as rs782453783; called by muse, mutect2, varscan2
- WDR90 | c.1392C>T p.S464= | Silent (SNP) | VAF 137/261 reads (52%) | catalogued as rs368146656; called by muse, mutect2, varscan2
- ZBTB10 | c.1323C>T p.T441= | Silent (SNP) | VAF 118/271 reads (44%) | catalogued as rs767010302; called by muse, mutect2, varscan2
- ZNF174 | c.921G>A p.L307= | Silent (SNP) | VAF 171/399 reads (43%) | called by muse, mutect2, varscan2
- ZNF592 | c.1086G>A p.P362= | Silent (SNP) | VAF 354/709 reads (50%) | catalogued as rs759430463, COSV55434991; called by muse, mutect2, varscan2
- ZSCAN2 | c.1422C>T p.Y474= | Silent (SNP) | VAF 116/268 reads (43%) | catalogued as rs372996130; called by muse, mutect2, varscan2
- ZSWIM4 | c.816C>T p.G272= | Silent (SNP) | VAF 159/338 reads (47%) | catalogued as rs963305187; called by muse, mutect2, varscan2
- AC008758.3 | n.1147C>T | RNA (SNP) | VAF 154/344 reads (45%) | called by muse, mutect2, varscan2
- AC134312.1 | n.1028dup | RNA (INS) | VAF 79/226 reads (35%) | called by mutect2, pindel, varscan2
- ACP2 | c.639+66C>T | Intron (SNP) | VAF 227/506 reads (45%) | catalogued as rs1189501638; called by muse, mutect2, varscan2
- ADGRL2 | c.3625+815del | Intron (DEL) | VAF 24/49 reads (49%) | catalogued as rs540574861; called by mutect2, varscan2
- AL109984.1 | n.186+5072G>T | Intron (SNP) | VAF 215/487 reads (44%) | catalogued as COSV63751961; called by muse, mutect2, varscan2
- ANKRD36 | c.1430-978dup | Intron (INS) | VAF 20/57 reads (35%) | catalogued as rs777547797; called by mutect2, varscan2
- AP000769.5 | chr11:65500581 C>T | 5'Flank (SNP) | VAF 130/255 reads (51%) | catalogued as rs755618497; called by muse, mutect2, varscan2
- ATAD3A | chr1:1509262 G>A | 5'Flank (SNP) | VAF 173/441 reads (39%) | catalogued as rs753025056; called by muse, mutect2, varscan2
- BCHE | c.1685-4272G>T | Intron (SNP) | VAF 95/216 reads (44%) | called by muse, mutect2, varscan2
- BEST1 | c.1739+128C>T | Intron (SNP) | VAF 40/87 reads (46%) | catalogued as rs571740954, COSV99861321; called by muse, mutect2, varscan2
- BTF3 | c.575-30dup | Intron (INS) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- C2CD6 | c.1581+2437G>A | Intron (SNP) | VAF 101/206 reads (49%) | catalogued as rs759793101; called by muse, mutect2, varscan2
- C3orf18 | c.*707del | 3'UTR (DEL) | VAF 54/151 reads (36%) | catalogued as rs1275428648; called by mutect2, pindel, varscan2
- C8orf82 | c.157-334del | Intron (DEL) | VAF 63/181 reads (35%) | catalogued as rs1172643553; called by mutect2, pindel, varscan2
- C9orf116 | c.143+224dup | Intron (INS) | VAF 76/263 reads (29%) | catalogued as rs1170595299; called by mutect2, pindel, varscan2
- CACNB4 | c.148-88135G>A | Intron (SNP) | VAF 144/300 reads (48%) | catalogued as rs1009244112; called by muse, mutect2, varscan2
- CAPN1 | chr11:65181670 del C | 5'Flank (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- CARD9 | c.1269+78G>A | Intron (SNP) | VAF 39/98 reads (40%) | catalogued as rs762471346; called by muse, mutect2, varscan2
- CD55 | c.1081+1135dup | Intron (INS) | VAF 118/306 reads (39%) | called by mutect2, pindel, varscan2
- CELF2 | c.1076-2187C>T | Intron (SNP) | VAF 103/206 reads (50%) | catalogued as rs761736942; called by muse, mutect2, varscan2
- CEP104 | c.566+1596C>T | Intron (SNP) | VAF 66/117 reads (56%) | catalogued as rs1239972500; called by muse, mutect2, varscan2
- CFLAR | c.662-23G>A | Intron (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- CLK2P1 | n.1291G>A | RNA (SNP) | VAF 78/142 reads (55%) | catalogued as rs754640471; called by muse, mutect2, varscan2
- CPLANE1 | c.*2645del | 3'UTR (DEL) | VAF 97/256 reads (38%) | catalogued as rs769153428, CD150481; called by mutect2, pindel, varscan2
- CTAG2 | c.-56C>T | 5'UTR (SNP) | VAF 54/211 reads (26%) | catalogued as rs782375900; called by muse, mutect2, varscan2
- DENND4B | c.-3del | 5'UTR (DEL) | VAF 27/60 reads (45%) | catalogued as rs770832731; called by mutect2, varscan2
- DGLUCY | c.1701+76C>T | Intron (SNP) | VAF 13/151 reads (9%) | catalogued as rs576337350; called by muse, mutect2
- DIP2A | c.1922-82G>A | Intron (SNP) | VAF 88/88 reads (100%) | catalogued as rs768096198; called by muse, mutect2, varscan2
- DKC1 | c.-15G>A | 5'UTR (SNP) | VAF 271/607 reads (45%) | catalogued as rs373433875; called by muse, mutect2, varscan2
- DNLZ | c.228+25G>A | Intron (SNP) | VAF 169/574 reads (29%) | called by muse, mutect2, varscan2
- DNM1P47 | n.2700C>T | RNA (SNP) | VAF 152/1912 reads (8%) | catalogued as rs752064701; called by muse, varscan2
- DTNBP1 | c.812-625C>T | Intron (SNP) | VAF 192/479 reads (40%) | catalogued as rs761888199; called by muse, mutect2, varscan2
- EBAG9 | c.522-1031A>G | Intron (SNP) | VAF 57/104 reads (55%) | catalogued as rs1363384008; called by muse, mutect2, varscan2
- EDA | c.396+4212G>T | Intron (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- ELFN1 | c.-456+5677C>T | Intron (SNP) | VAF 39/72 reads (54%) | catalogued as rs1464238548; called by muse, mutect2, varscan2
- ERBB4 | c.2487+37del | Intron (DEL) | VAF 88/239 reads (37%) | called by mutect2, pindel, varscan2
- ERGIC3 | chr20:35560147 G>A | 3'Flank (SNP) | VAF 129/245 reads (53%) | catalogued as rs1335918330; called by muse, mutect2, varscan2
- FAM20A | c.*742del | 3'UTR (DEL) | VAF 94/222 reads (42%) | catalogued as rs772873230; called by mutect2, varscan2
- FBLN2 | c.*227C>T | 3'UTR (SNP) | VAF 68/132 reads (52%) | called by muse, mutect2, varscan2
- FBXO30 | chr6:145791681 C>A | 3'Flank (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- FHL1 | c.*215A>G | 3'UTR (SNP) | VAF 94/273 reads (34%) | called by muse, mutect2, varscan2
- FN3K | c.591+51C>T | Intron (SNP) | VAF 233/466 reads (50%) | catalogued as rs772197390, COSV56182459; called by muse, mutect2, varscan2
- GATM | c.288+33C>T | Intron (SNP) | VAF 162/306 reads (53%) | catalogued as rs768844434; called by muse, mutect2, varscan2
- GCH1 | c.*17-63del | Intron (DEL) | VAF 48/54 reads (89%) | catalogued as rs918838734; called by mutect2, varscan2
- GDF6 | c.*2G>A | 3'UTR (SNP) | VAF 172/412 reads (42%) | catalogued as rs200117791; called by muse, mutect2, varscan2
- GGTLC2 | chr22:22643879 C>T | 5'Flank (SNP) | VAF 406/989 reads (41%) | catalogued as rs879541593; called by muse, mutect2, varscan2
- INSL3 | chr19:17821522 C>T | 5'Flank (SNP) | VAF 36/61 reads (59%) | catalogued as rs369090214; called by muse, mutect2, varscan2
- ITGB1BP2 | c.-7C>T | 5'UTR (SNP) | VAF 114/242 reads (47%) | catalogued as rs749756910; called by muse, mutect2, varscan2
- KCND3 | c.-29C>T | 5'UTR (SNP) | VAF 208/420 reads (50%) | catalogued as rs1261568072, COSV56178598; called by muse, mutect2, varscan2
- LARGE1 | c.615+26C>T | Intron (SNP) | VAF 219/413 reads (53%) | catalogued as rs774775433; called by muse, mutect2, varscan2
- LBH | c.26+461C>T | Intron (SNP) | VAF 33/81 reads (41%) | catalogued as rs1381671527; called by muse, mutect2, varscan2
- LINC01100 | n.167del | RNA (DEL) | VAF 89/282 reads (32%) | called by mutect2, pindel, varscan2
- LMO2 | c.-272+605G>A | Intron (SNP) | VAF 166/358 reads (46%) | catalogued as rs199607300; called by muse, mutect2, varscan2
- LSM14B | c.427+1315G>A | Intron (SNP) | VAF 267/552 reads (48%) | catalogued as rs1228884300; called by muse, mutect2, varscan2
- MIR520D | n.28G>A | RNA (SNP) | VAF 96/110 reads (87%) | called by muse, mutect2, varscan2
- MKRN9P | n.55del | RNA (DEL) | VAF 71/113 reads (63%) | called by mutect2, varscan2
- MTCL1 | c.2968-3220del | Intron (DEL) | VAF 84/184 reads (46%) | called by mutect2, varscan2
- NACA | c.71-4861C>T | Intron (SNP) | VAF 256/402 reads (64%) | called by muse, mutect2, varscan2
- NEU4 | c.457+373del | Intron (DEL) | VAF 84/186 reads (45%) | catalogued as rs1018792174; called by mutect2, pindel, varscan2
- NHP2 | c.336+11C>T | Intron (SNP) | VAF 273/512 reads (53%) | catalogued as rs369560609; called by muse, mutect2, varscan2
- NOS1AP | c.454-1211del | Intron (DEL) | VAF 44/126 reads (35%) | catalogued as rs1557885500; called by mutect2, pindel, varscan2
- NPIPB1P | n.1079G>A | RNA (SNP) | VAF 254/558 reads (46%) | catalogued as rs759101230; called by muse, varscan2
- NUTM2F | c.*5C>T | 3'UTR (SNP) | VAF 47/63 reads (75%) | catalogued as rs1325259098, COSV99479831; called by mutect2, varscan2
- PLEKHA6 | c.1525-960G>A | Intron (SNP) | VAF 59/143 reads (41%) | catalogued as rs779093314, COSV99692982; called by muse, mutect2, varscan2
- PLEKHM1P1 | n.660C>T | RNA (SNP) | VAF 259/545 reads (48%) | catalogued as rs766393483; called by muse, mutect2, varscan2
- POLG | c.2734+13C>T | Intron (SNP) | VAF 316/672 reads (47%) | catalogued as rs756271228; called by muse, mutect2, varscan2
- PPP4R1L | n.1720A>G | RNA (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- PRDX4 | c.476+35del | Intron (DEL) | VAF 106/251 reads (42%) | called by mutect2, varscan2
- PRPF31 | c.-8-19C>T | Intron (SNP) | VAF 219/220 reads (100%) | catalogued as rs373990452; called by muse, mutect2, varscan2
- PTAR1 | c.982+14C>T | Intron (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- PUSL1 | c.700-89C>T | Intron (SNP) | VAF 221/495 reads (45%) | catalogued as rs548777597; called by muse, mutect2, varscan2
- PXN | c.14-313G>A | Intron (SNP) | VAF 371/605 reads (61%) | catalogued as rs898020143; called by muse, mutect2, varscan2
- RABGEF1 | c.635-546C>T | Intron (SNP) | VAF 40/105 reads (38%) | catalogued as rs755284429; called by muse, mutect2, varscan2
- RANBP1 | c.310+246C>T | Intron (SNP) | VAF 116/215 reads (54%) | catalogued as rs755478450; called by muse, mutect2, varscan2
- RPAIN | c.314-511C>T | Intron (SNP) | VAF 24/57 reads (42%) | catalogued as rs1330664977; called by muse, mutect2
- SCN4B | c.*2330T>A | 3'UTR (SNP) | VAF 242/479 reads (51%) | catalogued as rs1445145488, COSV100228811; called by muse, mutect2, varscan2
- SGSM3 | c.2172+51G>A | Intron (SNP) | VAF 96/186 reads (52%) | catalogued as rs377041526; called by muse, mutect2, varscan2
- SLC29A3 | c.*385G>A | 3'UTR (SNP) | VAF 176/338 reads (52%) | catalogued as rs748101019; called by muse, mutect2, varscan2
- SLC47A1 | c.*1C>T | 3'UTR (SNP) | VAF 111/224 reads (50%) | catalogued as rs374839177; called by muse, mutect2, varscan2
- SRSF7 | c.-27_-26del | 5'UTR (DEL) | VAF 111/304 reads (37%) | called by mutect2, pindel, varscan2
- STK10 | c.2767-418G>A | Intron (SNP) | VAF 88/269 reads (33%) | catalogued as rs528354427, COSV51570360; called by muse, mutect2, varscan2
- TNFRSF1B | c.-7C>A | 5'UTR (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- TPSD1 | chr16:1262931 del G | 3'Flank (DEL) | VAF 126/296 reads (43%) | catalogued as rs1276808820; called by mutect2, varscan2
- TSPAN15 | c.*631G>A | 3'UTR (SNP) | VAF 148/317 reads (47%) | called by muse, mutect2, varscan2
- TXNRD2 | c.949+263A>C | Intron (SNP) | VAF 34/361 reads (9%) | called by muse, mutect2
- Unknown | chr2:217713090 ins C | IGR (INS) | VAF 116/275 reads (42%) | catalogued as rs148961389; called by mutect2, varscan2
- WLS | c.379+10364G>A | Intron (SNP) | VAF 40/113 reads (35%) | catalogued as rs758437066; called by muse, mutect2, varscan2
- ZNF169 | c.256+378C>T | Intron (SNP) | VAF 9/28 reads (32%) | catalogued as rs1298887380; called by muse, mutect2, varscan2
